Surgical pathology report (de-identified scan), TCGA case TCGA-RY-A843, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of California San Francisco, specimen TCGA-RY-A843-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED] Visit #: [REDACTED]
DOB: [REDACTED] Sex: [REDACTED]
Soc. Sec. #: [REDACTED] Location: [REDACTED]
Physician(s): [REDACTED]

Accession #: [REDACTED]
Service Date: [REDACTED]
Received: [REDACTED]
Client: [REDACTED]

ICD-O.3
Astrocytoma, grade III 9401/3
Site Brain supratentorial NOS
C71.0
C71.2
① Brain, temporal lobe

FINAL PATHOLOGIC DIAGNOSIS

- A. Brain, left temporal lobe, excision: Anaplastic Astrocytoma, WHO grade III; see comment.
- B. Brain, left temporal lobe, excision: Anaplastic Astrocytoma, WHO grade III; see comment.

COMMENT:

H&E sections of this astrocytoma show multiple areas of increased cellularity and mitotic activity (up to 4 MF/10 HPF), consistent with an anaplastic astrocytoma, WHO grade III. Immunohistochemistry for IDH-1 (R132H mutant protein), p53, and MIB-1 was performed and evaluated on block A5. The neoplasm is strongly positive for IDH-1, and approximately 25% of the cells are positive for p53. The MIB-1 labeling index is estimated at approximately 8% within areas of highest staining.

Intraoperative Diagnosis

FS1 (A) Brain, left temporal lobe, excision: Infiltrating astrocytoma, favor astrocytic, no high-grade features on frozen section.

Gross Description

The specimen is received in fresh in two parts, each labeled with the patient's name and medical record number.

Part A, labeled "left frontal lobe tumor," consists of a single unoriented fragment of soft tan-brown tissue (3.3 x 1.8 x 1.4 cm). A portion of the specimen is submitted for frozen section diagnosis 1, with the remnant submitted in cassette A1. The unfrozen portion of the specimen is sectioned and completely submitted in cassettes A2-A5.

Part B, labeled "left temporal lobe tumor, permanent," consists of a single unoriented fragment of soft tan-brown tissue (2 x 2 x 1.3 cm). The specimen is serially sectioned and entirely submitted in cassettes B1 to B4.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the

[page 2 of 2]
[REDACTED]

They have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing.

Clinical History

The patient is a [REDACTED] year old man with partial complex seizures and language disturbance who undergoes resection of a diffuse infiltrating, left frontotemporal tumor.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides. The attending pathologist has reviewed all dictations and preliminary interpretations performed by any resident involved in the case and performed all necessary edits before signing the final report.

[REDACTED]

	Yes	No
Metastasis		/
Metastatic/Synchronous Primary Noted		/
Case is (check one) Reviewed by [Signature]	QUALIFIED	DISQUALIFIED

Source: NCI Genomic Data Commons file 00a8066f-75e2-4821-a760-be24e7b92cf2 (TCGA-RY-A843.2C380241-843C-4301-8891-78345D97CC08.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).